Somatic mutation profile of tumor specimen TCGA-UT-A97Y-01A (aliquot TCGA-UT-A97Y-01A-21D-A39R-32) from TCGA case TCGA-UT-A97Y, project TCGA-MESO (Mesothelioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Epithelioid mesothelioma, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 81.9 years (29,905 days).
Specimen TCGA-UT-A97Y-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 00188860-aac3-4185-ab89-c5f7461b1273.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-UT-A97Y-10A (Blood Derived Normal), aliquot TCGA-UT-A97Y-10A-01D-A39U-32; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/02750f88-7077-4a9a-8bff-a6c8665572c0

The open-access MAF lists 33 somatic variants for this specimen: 18 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 14, Frame Shift Del 2, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FAM122B | c.139C>T p.R47W | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs766514226; called by muse, mutect2, varscan2
- H1-3 | c.107C>T p.A36V | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.259); catalogued as rs201679688; called by muse, mutect2, varscan2
- LCMT1 | c.982G>T p.G328W | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66725748; called by muse, mutect2, varscan2
- NF2 | c.675+1del | Frame Shift Del (DEL) | VAF 5/46 reads (11%) | catalogued as COSV58527485; called by mutect2, pindel, varscan2
- PTPRU | c.2570C>T p.P857L | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0.036); catalogued as COSV100113642; called by muse, mutect2, varscan2
- TECTB | c.904C>T p.R302W | Missense Mutation (SNP) | VAF 29/185 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as rs374612200; called by muse, mutect2, varscan2
- TSC2 | c.4078G>A p.E1360K | Missense Mutation (SNP) | VAF 11/142 reads (8%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.077); catalogued as rs397514997; ClinVar: benign; called by muse, mutect2
- ASXL3 | c.1445G>T p.S482I | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- BAP1 | c.680_704del p.R227Pfs*14 | Frame Shift Del (DEL) | VAF 14/136 reads (10%) | called by mutect2, pindel
- GPATCH8 | c.4137C>G p.I1379M | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); called by muse, mutect2
- MFSD2B | c.286C>G p.P96A | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MGME1 | c.820G>T p.A274S | Missense Mutation (SNP) | VAF 20/145 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SIGLEC10 | c.1709+1G>A p.X570_splice | Splice Site (SNP) | VAF 8/92 reads (9%) | called by muse, mutect2
- TNRC6A | c.392G>A p.R131Q | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); called by muse, mutect2
- TRERF1 | c.1583A>T p.N528I | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TYMS | c.145G>A p.D49N | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.756); called by muse, mutect2
- USP9X | c.6605C>G p.P2202R | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.736); called by muse, mutect2, varscan2
- ZNF766 | c.1276C>T p.L426F | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- C1QBP | c.10C>T p.L4= | Silent (SNP) | VAF 5/22 reads (23%) | called by muse, mutect2
- C3orf20 | c.180G>A p.V60= | Silent (SNP) | VAF 18/181 reads (10%) | catalogued as rs916422269; called by muse, mutect2, varscan2
- DENND1B | c.567T>C p.N189= | Silent (SNP) | VAF 8/108 reads (7%) | called by muse, mutect2
- DSP | c.900C>T p.D300= | Silent (SNP) | VAF 6/64 reads (9%) | called by mutect2, varscan2
- GPRC5C | c.565C>T p.L189= (on ENST00000652232; = p.L144= on NM_018653.4) | Silent (SNP) | VAF 12/174 reads (7%) | called by muse, mutect2
- HSPG2 | c.5355C>T p.P1785= | Silent (SNP) | VAF 19/155 reads (12%) | catalogued as rs185977135; called by muse, mutect2, varscan2
- MGAT4C | c.657T>C p.Y219= | Silent (SNP) | VAF 7/52 reads (13%) | called by muse, mutect2, varscan2
- MOCS3 | c.498C>G p.A166= | Silent (SNP) | VAF 35/195 reads (18%) | called by muse, mutect2, varscan2
- OR51E1 | c.837C>T p.A279= | Silent (SNP) | VAF 12/116 reads (10%) | called by muse, mutect2
- PHC3 | c.729G>A p.L243= (on ENST00000494943 / NM_001308116.2; = p.L255= on NM_024947.4) | Silent (SNP) | VAF 12/142 reads (8%) | called by muse, mutect2
- RAPGEF1 | c.1686G>A p.S562= | Silent (SNP) | VAF 26/194 reads (13%) | catalogued as rs937593427, COSV64702697; called by muse, mutect2, varscan2
- SLC30A1 | c.597C>T p.S199= | Silent (SNP) | VAF 9/76 reads (12%) | called by muse, mutect2, varscan2
- SOWAHA | c.1212G>A p.L404= | Silent (SNP) | VAF 8/70 reads (11%) | called by muse, mutect2, varscan2
- XPNPEP2 | c.393C>G p.L131= | Silent (SNP) | VAF 5/51 reads (10%) | catalogued as COSV64367852; called by muse, mutect2, varscan2
- MIR668 | n.22C>T | RNA (SNP) | VAF 9/77 reads (12%) | called by muse, mutect2
